Surgical pathology report (de-identified scan), TCGA case TCGA-FA-A4BB, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Asterand, specimen TCGA-FA-A4BB-01A (Primary Tumor).

Gross Description: In the fatty tissue there are enlarged soft hyperemic lymph nodes up to 3.5 cm in their diameter.

Microscopic Description: Diffuse large B-cell lymphoma. IHC-stainings: CD45 - positive reaction; CD20 - positive reaction; CD3 - negative reaction in the tumor cells, positive reaction on the reactive cells; CD30 - positive reaction in some tumor cells.

Diagnosis Details: Tumor Features: Indeterminate, Tumor Extent: Disseminated (multifocal) involvement, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments: Extranodal involvement -- liver, spleen.

Formatted Path Reports: Lymphoma Checklist

ICD-0-3

Tumor site: Lymph node

lymphoma, diffuse, large B-cell
9680/3

Tumor location: Lymph node

Site: lymph node, axilla C77.3

Tumor size: 3.5 cm

fw 9/26/12

Histological type: Diffuse large B-cell lymphoma

Tumor Features: Indeterminate

Tumor Extent: Disseminated (multifocal) involvement

Extranodal involvement -- liver, spleen.

Lymph Nodes: 5/5 positive, axillary, inguinal

Venous Invasion: Absent

Margins: Uninvolved

Additional pathologic findings:

IHC-stainings: CD45 - positive reaction; CD20 - positive reaction; CD3 - negative reaction in the tumor cells, positive reaction on the reactive cells; CD30 - positive reaction in some tumor cells.

Case is (Single):		
Reviewed and		

fw 9/26/12

8/23/12

Source: NCI Genomic Data Commons file bae7c1ad-0ccf-4d3f-97ed-e55660b002df (TCGA-FA-A4BB.05B34041-D414-4215-9A66-2B7E4D09F4D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).